TCGA case TCGA-64-1681 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Fox Chase. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c583fdd1-8cd2-4c15-a23e-0644261f65da

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 61 years; Vital status: Dead; Days to death: 1,167 days (3.2 years).

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 61.7 years (22,525 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Erlotinib Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 481 days (1.3 years); Prescribed dose: 150; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment start: 711 days (1.9 years); Treatment dose: 3,000 cGy; Course number: 1; Treatment anatomic sites: Distant Site.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 62.9 years (22,964 days); Days to diagnosis: 439 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Locoregional Site.

Follow-up (3 entries)
- Day 439 (post initial treatment): Progression or recurrence: Yes.
- Karnofsky performance status: 0.
- Follow-up contact recording only the day: day 1,167.

Molecular and laboratory tests
- EGFR deletion: Positive; Exon: 19.
- KRAS mutation, nos: Negative.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Tobacco smoking onset year: 1968; Tobacco smoking quit year: 1988.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-64-1681-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.4; Shortest dimension: 0.4.
  Slide TCGA-64-1681-01A-01-BS1: Section location: Bottom; Percent tumor cells: 30; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 30; Percent stromal cells: 40; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 5.
  Slide TCGA-64-1681-01A-01-TS1: Section location: Top; Percent tumor cells: 5; Percent tumor nuclei: 15; Percent normal cells: 0; Percent necrosis: 90; Percent stromal cells: 5; Percent lymphocyte infiltration: 85; Percent monocyte infiltration: 9; Percent neutrophil infiltration: 5.
- Sample TCGA-64-1681-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-64-1681-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tobacco smoking history indicator: 3; Anatomic organ subdivision: R-Upper; KRAS mutation found: No; KRAS gene analysis indicator: Yes; EGFR mutation status: Yes; EGFR mutation identified type: Exon 19 Deletion.
- Drug treatment: Regimen number: 1; Pharmaceutical therapy drug name: Tarceva; Therapy regimen: Recurrence.
- Drug treatment, Route of administrations: Route of administration: PO.
- Follow-up form: New tumor event diagnosis indicator: Yes; New tumor event surgery: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,167 days; disease-specific survival: event status not recorded, 1,167 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 439 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-64-1681-01A-11D-2062-01): tumor purity 0.31, ploidy 5.63, whole-genome doublings 2.
